Surgical pathology report (de-identified scan), TCGA case TCGA-06-0139, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0139-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED] 12-0139

[REDACTED]

Surgical Pathology Report

[REDACTED]

=====

CLINICAL HISTORY

[REDACTED] has previous diagnosis of anaplastic astrocytoma on a temporal lobe biopsy.

OPERATIVE DIAGNOSES

Craniotomy/tumor (brain).

Operation/Specimen: A: Medial temporal, Brain, biopsyIn formalin

B: Medial Temporal, Brain, biopsy

C: Hypocampus, Brain, biopsy

D: Medial temporal, Brain, biopsy

E: Posterior, Brain, biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, C, D, and E. Brain, medial temporal, hippocampus, and posterior temporal lobe, excision: Glioblastoma, with extensive necrosis. MIB-1 proliferation index: 15%.

See comment.

COMMENT

All the specimens consist of brain tissue and a neoplastic proliferation of astrocytes with mitotic figures, focal microvascular cellular proliferation, thrombosis of microvessels throughout, and extensive zones of necrosis. The bulk of the specimens (approximately 90%) is necrotic, with only small portions of viable, diagnostic tissue. In the hippocampus (part C) the neoplasm is sparsely infiltrative, with microscopic foci of subependymal spread. The MIB-1 proliferation index is up to 15% in the more active areas.

[REDACTED]

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

[REDACTED]

Interpretation

Block A2: POSITIVE - Methylated MGMT promoter is detected.

Block A3: NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

[REDACTED]

[page 2 of 4]
TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

=====

INTRA-OPERATIVE CONSULTATION

B. Medial Temporal, Brain, touch prep and smears: Spindle cell neoplasm with necrosis [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

A. Medial temporal, Brain, biopsy formalin:

FIXATIVE: Formalin

GENERAL: Received in formalin are 2 tan- yellow irregular soft friable fragments of tissue ranging from 1.7-2 cm in greatest dimensions.

CASSETTES: A1-A4, all submitted

B. Medial Temporal, Brain, biopsy:

FIXATIVE: none

GENERAL: Received fresh is a single 1.1 x 1 x 0.5 cm irregular soft tan fragment submitted for frozen section diagnosis.

CASSETTES: B1-B4, all submitted

C.

SPECIMEN: Hippocampus.

FIXATIVE: Formalin.

GENERAL: A 1.5 x 1.4 x 0.5 cm., 0.57 gm. red to gray-white fragment of brain tissue. Sectioned through its short axis.

SECTIONS: C1 - all submitted.

D.

SPECIMEN: Medial temporal tumor.

FIXATIVE: Formalin.

GENERAL: A 2.0 x 1.8 x 1.4 cm., 1.74 gm. aggregate of several irregularly shaped, red to gray-tan fragments of brain tissue. The largest fragment is sectioned.

SECTIONS: D1, D2 - all submitted.

E.

SPECIMEN: Posterior tumor.

FIXATIVE: Formalin.

GENERAL: A 1.3 x 1.1 x 0.7 cm., 0.57 gm. aggregate of a couple irregularly shaped, gray-tan tissue fragments with minimal focally adherent blood clot.

[page 3 of 4]
SECTIONS: E1 - all submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates heavy glial fibrillogenesis by the neoplastic cells. The KP1 and MAC387 demonstrate few viable phagocytic cells and large amounts of tissue debris, respectively. The CD34 depicts extensive abnormal angiogenesis, with focal perivascular cellular proliferation. With the MIB-1, a proliferation index of up to 15% is determined in the more active areas. The immuno results support the diagnosis of a high histological grade astrocytic neoplasm.

ICD-9(s):
191.2 191.2

Histo Data

Part A: Medial temporal, Brain, biopsy in formalin

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
MGMT x 1	2		
CD34-DA x 1	3		
mGFAP-DA x 1	3		
H/E x 1	3		
KP1-DA x 1	3		
MAC387-DA x 1	3		
MGMT x 1	3		
MIB1-DA x 1	3		
H/E x 1	4		

Part B: Medial Temporal, Brain, biopsy

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
H/E x 1	3		
H/E x 1	4		

Part C: Hypocampus, Brain, biopsy

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		

Part D: Medial temporal, Brain, biopsy

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
CD34-DA x 1	2		

[page 4 of 4]
mGFAP-DA x 1 2
H/E x 1 2
KP1-DA x 1 2
MAC387-DA x 1 2
MIB1-DA x 1 2
M Trich x 1 2

Part E: Posterior, Brain, biopsy

Stain/Cnt	Block	Ordered	Comment
H/E x 1	1		

*** End of Report ***

Source: NCI Genomic Data Commons file f6ac79d8-8eb5-448a-a78d-1e67422e62aa (TCGA-06-0139.964DF5A7-62AA-4CD7-B6AD-E41F27747616.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).